TARGET case TARGET-30-PAKZMI — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/98d81ecd-2770-5f0f-868b-3b45b45e98dd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.1 years (770 days); Year of diagnosis: 2001; Days to last follow up: 192 days; INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAKZMI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
